Somatic mutation profile of tumor specimen TCGA-BR-4363-01A (aliquot TCGA-BR-4363-01A-01D-1158-08) from TCGA case TCGA-BR-4363, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G3; Age at diagnosis: 60.8 years (22,196 days).
Specimen TCGA-BR-4363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9fbbb8-9b6b-428b-b781-0b5fbd43aa20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4363-11A (Solid Tissue Normal), aliquot TCGA-BR-4363-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a9a696f-abc9-4757-ad32-ad2d1a076331

The open-access MAF lists 704 somatic variants for this specimen: 550 protein-altering or splice-affecting, 140 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 316, Frame Shift Del 180, Silent 140, Frame Shift Ins 21, Nonsense Mutation 17, Splice Region 6, In Frame Del 6, Intron 6, RNA 4, Splice Site 4, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as rs1559959758, CM124146, COSV56136763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 44/203 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as rs755782051, CM1515267, COSV57635223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A1 | c.1163del p.F388Sfs*40 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | catalogued as rs779588655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- STK11 | c.169del p.E57Kfs*7 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs121913319, CD044165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 52/178 reads (29%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A3GALT2 | c.228del p.W77Gfs*29 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs745494792; called by mutect2, pindel, varscan2
- ABCB10 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332666020, COSV60624594; called by muse, mutect2, varscan2
- AC011455.2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs777764275, COSV55498475; called by muse, mutect2, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel, varscan2
- ACTL10 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs937711882, COSV55779043; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 73/196 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS18 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51411130, COSV51424470; called by muse, mutect2, varscan2
- ADCY5 | c.2026del p.A676Lfs*18 | Frame Shift Del (DEL) | VAF 69/278 reads (25%) | catalogued as rs151195921, COSV59195616; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ADGRG2 | c.1061C>T p.A354V (on ENST00000379869 / NM_001079858.3; = p.A351V on NM_005756.4) | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1254226753, COSV61339022, COSV61341057; called by muse, mutect2, varscan2
- ADGRV1 | c.8378G>T p.R2793M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV67981710, COSV67996914; called by muse, mutect2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 86/170 reads (51%) | catalogued as rs761350619; called by mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- ALDH9A1 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 59/208 reads (28%) | catalogued as rs866901450, COSV61341844; called by muse, mutect2, varscan2
- ALKBH7 | c.656del p.P219Qfs*23 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs767513504; called by mutect2, pindel, varscan2
- ALPK3 | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); catalogued as COSV51941429; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | catalogued as rs34047276; called by mutect2, varscan2
- ANKEF1 | c.1991C>A p.P664H | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV65694047; called by muse, mutect2, varscan2
- ANKEF1 | c.2247G>T p.E749D | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV65694051; called by muse, mutect2, varscan2
- ANKRD17 | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs1338498270, COSV58229129; called by muse, mutect2, varscan2
- ANO7 | c.189G>T p.E63D (on ENST00000274979; = p.E9D on NM_001001666.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.479); catalogued as COSV51480520; called by muse, mutect2, varscan2
- ANO9 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs199703326, COSV60452424; called by muse, mutect2, varscan2
- ANO9 | c.772-3del | Splice Region (DEL) | VAF 8/34 reads (24%) | catalogued as rs535142896; called by mutect2, pindel
- ANPEP | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs374140510, COSV55590531; called by muse, mutect2, varscan2
- ANXA5 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56640445; called by muse, mutect2, varscan2
- AOC2 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53200484; called by muse, mutect2, varscan2
- ARGLU1 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV62272011; called by muse, mutect2, varscan2
- ARHGEF37 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 111/389 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61370607; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | catalogued as rs749402223; called by mutect2, varscan2
- ARHGEF6 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 97/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51694128, COSV51696899; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARID2 | c.4999T>C p.C1667R | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57616714; called by muse, mutect2
- ARL4D | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60722010; called by muse, mutect2, varscan2
- ASPM | c.9577C>T p.R3193C | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140679756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN1 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.088); catalogued as COSV56089777; called by muse, mutect2, varscan2
- ATP1A1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV55194791; called by muse, mutect2, varscan2
- ATP2B2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1057261655, COSV59490646, COSV59499981; called by muse, mutect2, varscan2
- B4GALNT3 | c.1151G>T p.S384I | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56759056; called by muse, mutect2, varscan2
- BCL11B | c.1691G>A p.R564H (on ENST00000357195 / NM_001282237.2; = p.R493H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs1271709759, COSV100596027; called by muse, mutect2, varscan2
- BCOR | c.4523del p.G1508Afs*60 (on ENST00000378444 / NM_001123385.2; = p.G1474Afs*60 on NM_017745.6) | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as COSV100654502; called by mutect2, pindel, varscan2
- BECN1 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV64121273; called by muse, mutect2, varscan2
- BRDT | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.275); catalogued as rs1363980091, COSV61771388; called by muse, mutect2
- C11orf54 | c.926C>T p.T309M (on ENST00000331239; = p.T259M on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs552777927, COSV58682555; called by muse, mutect2, varscan2
- C11orf71 | c.323A>C p.Q108P | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV57784974; called by muse, varscan2
- C1QL4 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.18); catalogued as COSV57746343; called by muse, mutect2, varscan2
- C1orf198 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs778320924, COSV64176378; called by muse, mutect2, varscan2
- C2orf42 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV52453351; called by muse, mutect2, varscan2
- CACNA1C | c.3142del p.V1048Sfs*58 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as COSV100214499, COSV59700715; called by mutect2, pindel, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CAD | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99256061; called by mutect2, varscan2
- CALCRL | c.923del p.F308Sfs*3 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs1422497140; called by mutect2, pindel
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 43/162 reads (27%) | catalogued as rs1375954479; called by pindel, varscan2
- CAND1 | c.1111T>A p.F371I | Missense Mutation (SNP) | VAF 117/362 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV73338685; called by muse, mutect2, varscan2
- CASKIN2 | c.2161G>A p.G721S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs955210900, COSV58600887; called by muse, mutect2, varscan2
- CASP8 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51848427, COSV51851206; called by muse, mutect2, varscan2
- CAT | c.1196-1G>T p.X399_splice | Splice Site (SNP) | VAF 87/244 reads (36%) | catalogued as COSV53813966; called by muse, mutect2, varscan2
- CCDC3 | c.798del p.Y267Tfs*21 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs750606155; called by mutect2, pindel, varscan2
- CCNB3 | c.3535C>T p.H1179Y | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52080987; called by muse, mutect2, varscan2
- CCND1 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs759765773, COSV57123737, COSV99919604; called by muse, mutect2, varscan2
- CDKAL1 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.177); catalogued as COSV51194572; called by muse, mutect2
- CECR2 | c.799C>T p.R267* (on ENST00000342247 / NM_001290047.2; = p.R104* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV52847607, COSV52850013; called by muse, mutect2, varscan2
- CEMIP | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.11); catalogued as rs1471372069, COSV55001584; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP45 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs777027378, COSV63651458; called by muse, mutect2
- CFAP74 | c.1146del p.T383Pfs*7 | Frame Shift Del (DEL) | VAF 53/195 reads (27%) | catalogued as rs771497538; called by mutect2, pindel, varscan2
- CFHR1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 41/192 reads (21%) | catalogued as COSV57628191; called by muse, mutect2, varscan2
- CHD4 | c.2842G>A p.D948N (on ENST00000357008 / NM_001363606.2; = p.D961N on NM_001273.5) | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58904170; called by muse, mutect2
- CHD5 | c.840del p.I281Sfs*185 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs1304823433; called by mutect2, pindel, varscan2
- CHST1 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs1391430094, COSV100346531, COSV57324224; called by muse, mutect2, varscan2
- CIC | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs777940595, COSV50684066; called by muse, mutect2, varscan2
- CKAP5 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56375252; called by muse, mutect2, varscan2
- CKMT2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572748774, COSV54175303; called by muse, mutect2, varscan2
- CLN3 | c.1180C>A p.L394M (on ENST00000360019 / NM_001286104.2; = p.L418M on NM_000086.2) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61108083; called by muse, mutect2, varscan2
- CNGA4 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs773908561, COSV66005104; called by muse, mutect2, varscan2
- CNTFR | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs747782591, COSV63635273; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs374805044; called by mutect2, varscan2
- COL4A1 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.036); catalogued as rs372803920, COSV65433024; called by muse, mutect2, varscan2
- COL5A1 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs758650140, COSV65676279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.4729C>T p.P1577S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV65675242; called by muse, mutect2, varscan2
- COL5A1 | c.5327A>G p.Y1776C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65676293; called by muse, mutect2, varscan2
- CPAMD8 | c.4307T>G p.L1436R (on ENST00000651564; = p.L1389R on NM_015692.5) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.586); catalogued as COSV101488641; called by muse, varscan2
- CPEB4 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs142106976; called by muse, mutect2, varscan2
- CPNE3 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV52211454; called by muse, mutect2, varscan2
- CRTAC1 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs761525287, COSV54011303; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 27/142 reads (19%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as rs866326670, COSV52347241, COSV99033785; called by muse, mutect2, varscan2
- CSNK1G1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs759122459, COSV57313403; called by muse, mutect2, varscan2
- CTIF | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs372476573; called by muse, mutect2, varscan2
- CYP4F2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs767226438, COSV55616173; called by muse, mutect2, varscan2
- DAAM1 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773103520, COSV62840382; called by muse, mutect2, varscan2
- DBNDD1 | c.107C>T p.T36M (on ENST00000002501 / NM_001042610.3; = p.T56M on NM_024043.3) | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as rs771885579, COSV50022757; called by muse, mutect2, varscan2
- DCC | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59143477; called by muse, mutect2, varscan2
- DCTN2 | c.578del p.G193Efs*39 (on ENST00000548249 / NM_001261413.2; = p.G198Efs*39 on NM_006400.4) | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | catalogued as COSV63074463; called by mutect2, pindel, varscan2
- DHRS12 | c.506G>A p.R169Q (on ENST00000444610 / NM_001377930.1; = p.R120Q on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as rs1390747293, COSV54473826; called by muse, mutect2, varscan2
- DHX8 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.371); catalogued as COSV52257200; called by muse, mutect2, varscan2
- DIDO1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs1234951354, COSV56635869; called by muse, mutect2, varscan2
- DMP1 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56822577; called by muse, mutect2, varscan2
- DMRTB1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778004738, COSV65114209; called by muse, mutect2, varscan2
- DNAH11 | c.13211C>T p.T4404M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768366183, COSV60963571; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH5 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs755574532, COSV54233163; called by muse, mutect2, varscan2
- DNAH9 | c.583dup p.M195Nfs*9 | Frame Shift Ins (INS) | VAF 45/187 reads (24%) | catalogued as rs754168239; called by mutect2, pindel, varscan2
- DNAJC15 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs752317033, COSV64872633; called by muse, mutect2, varscan2
- DPP9 | c.344C>T p.T115M (on ENST00000598800; = p.T144M on NM_139159.5) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs994294799, COSV53594978; called by muse, mutect2, varscan2
- DSCAML1 | c.1606del p.Q536Rfs*25 (on ENST00000321322; = p.Q476Rfs*25 on NM_020693.4) | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | catalogued as rs1172761928; called by mutect2, pindel, varscan2
- DUOX1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757808802, COSV58487385; called by muse, mutect2, varscan2
- DYSF | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775370021, COSV50269980; called by muse, mutect2, varscan2
- ECE1 | c.492C>T p.L164= | Splice Region (SNP) | VAF 18/71 reads (25%) | catalogued as rs1297396104, COSV51671630, COSV99941918; called by muse, mutect2, varscan2
- EDDM3A | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58795251; called by muse, mutect2, varscan2
- EEF1D | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1447049807, COSV52785272; called by muse, mutect2, varscan2
- EIF2B1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1245638011, COSV53015723; called by muse, mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as rs1554600455; called by mutect2, pindel, varscan2
- EPHA1 | c.2419A>G p.S807G | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51977341; called by muse, mutect2, varscan2
- EPHB1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 108/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67662422; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 76/122 reads (62%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.710T>C p.M237T | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1265707916, COSV57277261; called by muse, mutect2, varscan2
- EYA1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 112/619 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.909); catalogued as rs142104253; called by muse, mutect2, varscan2
- FAM117A | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53634406; called by muse, mutect2, varscan2
- FAM135B | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321133355, COSV52758375; called by muse, mutect2, varscan2
- FAM184A | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.881); catalogued as COSV58859468; called by muse, mutect2, varscan2
- FAM186B | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV57724331; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM47C | c.1964G>A p.C655Y | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); catalogued as rs1556332908, COSV63731052; called by muse, mutect2, varscan2
- FAM83A | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as COSV52688713; called by muse, mutect2, varscan2
- FAR2 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV51730593; called by muse, mutect2, varscan2
- FAT3 | c.12661G>A p.V4221I | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749339528, COSV53082658; called by muse, mutect2, varscan2
- FBXL7 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV61654733; called by muse, mutect2, varscan2
- FBXO3 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55768437; called by muse, mutect2, varscan2
- FBXO47 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753916869, COSV65242812; called by muse, mutect2, varscan2
- FERMT2 | c.168del p.D57Ifs*17 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | catalogued as rs1225761410; called by mutect2, pindel, varscan2
- FGD3 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV61600453; called by muse, mutect2, varscan2
- FHOD3 | c.3997G>A p.V1333I (on ENST00000359247 / NM_001281739.3; = p.V1350I on NM_025135.5) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs149906669; called by muse, mutect2
- FLNA | c.4909G>A p.V1637M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1333867692, COSV61053313; called by muse, mutect2, varscan2
- FMNL1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.437); catalogued as COSV58959986; called by muse, mutect2, varscan2
- FOXN1 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56884753; called by muse, mutect2, varscan2
- FRMPD3 | c.5107A>G p.I1703V | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99347356; called by muse, mutect2, varscan2
- FYN | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.301); catalogued as COSV57622483; called by muse, mutect2, varscan2
- GABRA6 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376700482, COSV50882721; called by muse, mutect2, varscan2
- GALNT14 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368328840, COSV61106479, COSV61108274; called by muse, mutect2, varscan2
- GAREM1 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV52513266, COSV52517045; called by muse, mutect2, varscan2
- GIGYF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.866); catalogued as rs866567776, COSV51947570; called by muse, mutect2, varscan2
- GJA1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 35/138 reads (25%) | catalogued as CM092832, COSV56997306; called by muse, mutect2, varscan2
- GLT8D1 | c.238dup p.A80Gfs*37 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | catalogued as rs754869681; called by mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA3 | c.3284G>A p.G1095D | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.736); catalogued as COSV52625826; called by muse, mutect2, varscan2
- GPR75 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs143781055; called by muse, mutect2, varscan2
- GPRIN2 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs529261744, COSV65402925; called by muse, mutect2, varscan2
- GRIA3 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV52083592; called by muse, mutect2, varscan2
- GRIA3 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52083638; called by muse, mutect2, varscan2
- GRM1 | c.1226A>T p.K409M | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51376196; called by muse, mutect2, varscan2
- GRM4 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs144674222; called by muse, mutect2, varscan2
- HAS2 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 109/584 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV58267924; called by muse, mutect2, varscan2
- HAUS7 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV57851571; called by muse, mutect2, varscan2
- HDX | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as COSV52984057; called by muse, mutect2, varscan2
- HELQ | c.1096A>C p.T366P | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55028517; called by muse, mutect2, varscan2
- HIPK1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1287481025, COSV65787090; called by muse, mutect2, varscan2
- HIVEP1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451041533, COSV65105757; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1558087190; called by mutect2, pindel, varscan2
- HNF4G | c.112C>T p.R38C (on ENST00000354370 / NM_001330561.2; = p.R85C on NM_004133.5) | Missense Mutation (SNP) | VAF 135/242 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772036366, COSV62965321; called by muse, mutect2, varscan2
- HOXC9 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs1424545623, COSV57716943; called by muse, mutect2, varscan2
- HUWE1 | c.6187A>G p.K2063E | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV53367112; called by muse, mutect2, varscan2
- HYAL3 | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); catalogued as COSV56499637; called by muse, mutect2, varscan2
- IFI16 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV55541234; called by muse, mutect2, varscan2
- IFT81 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs866734477, COSV54361300; called by muse, mutect2, varscan2
- IGFL3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs201383634; called by muse, mutect2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- INAVA | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV66257790; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSL6 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs758608116, COSV67562527; called by muse, mutect2, varscan2
- INSYN1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs771270220, COSV65837394; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs754482477, COSV100311029, COSV58029257; called by muse, mutect2, varscan2
- KBTBD4 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55456588; called by muse, mutect2, varscan2
- KCND1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1461767463, COSV54416397, COSV99501697; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNMB1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs374697787, COSV99211269; called by muse, mutect2, varscan2
- KCTD18 | c.371del p.K124Rfs*3 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs1559186306; called by mutect2, pindel
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KIAA1109 | c.7958G>A p.R2653Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs995194426, COSV52680650; called by muse, mutect2, varscan2
- KIF26B | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV63653693, COSV63654236; called by muse, mutect2, varscan2
- KIF3C | c.1891T>C p.Y631H | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53102658; called by muse, mutect2, varscan2
- KLHL3 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59058780; called by muse, mutect2, varscan2
- KLHL4 | c.1406T>G p.F469C | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV64149033; called by muse, mutect2
- KLHL5 | c.2145del p.Y716Mfs*28 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | catalogued as rs1213171273; called by mutect2, pindel, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 59/217 reads (27%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KRTAP26-1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV62129586; called by muse, mutect2, varscan2
- KY | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs536220579, COSV71018849; called by muse, mutect2, varscan2
- L3MBTL2 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV53436249; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 39/146 reads (27%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDAH | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs375801514; called by muse, mutect2, varscan2
- LDAH | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV52968875; called by muse, mutect2, varscan2
- LILRB5 | c.142T>G p.W48G | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1474743927, COSV60261657; called by muse, mutect2, varscan2
- LMAN1L | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59003972; called by muse, mutect2, varscan2
- LMNB2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs773444127, COSV57591298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LNX2 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs745613572, COSV60338718; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 79/249 reads (32%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP2 | c.8183G>T p.G2728V | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55578927; called by muse, mutect2
- LRR1 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as rs377149462; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRC4B | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs1294431299, COSV65351014; called by muse, mutect2, varscan2
- MAGEA10 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 126/494 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54886409; called by muse, varscan2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as COSV55811343; called by mutect2, pindel, varscan2
- MB21D2 | c.1371dup p.L458Tfs*7 | Frame Shift Ins (INS) | VAF 64/200 reads (32%) | catalogued as rs34835215; called by mutect2, varscan2
- MICAL2 | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV56289259; called by muse, mutect2, varscan2
- MIDEAS | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs754342203, COSV54099880; called by muse, mutect2, varscan2
- MINK1 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.468); catalogued as rs367931451; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MOGAT1 | c.132A>G p.I44M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV71480175; called by muse, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs757379917; called by mutect2, varscan2
- MPRIP | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375924665; called by muse, mutect2, varscan2
- MRGPRD | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs1302176041, COSV58424304; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs767880823; called by mutect2, varscan2
- MTSS2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376758699; called by muse, mutect2, varscan2
- MYH10 | c.3191C>T p.T1064M | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as rs201075759, COSV52613374; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 50/229 reads (22%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- MYT1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs139069988, COSV60505375; called by muse, mutect2, varscan2
- N4BP1 | c.2462G>A p.S821N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52213954; called by muse, mutect2, varscan2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs770577267; called by mutect2, varscan2
- NAA38 | c.304G>A p.A102T (on ENST00000575771 / NM_001320925.2; = p.A150T on NM_032356.5) | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV54688139; called by muse, mutect2, varscan2
- NAMPT | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV55997033; called by muse, mutect2, varscan2
- NAV3 | c.6206T>G p.L2069R (on ENST00000397909 / NM_001024383.2; = p.L2047R on NM_014903.6) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57094996, COSV57117688; called by muse, mutect2
- NCAN | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53060770; called by muse, mutect2, varscan2
- NCCRP1 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781215125, COSV59213268; called by muse, mutect2, varscan2
- NCOA5 | c.624_627del p.T209Kfs*17 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | catalogued as rs1292571147; called by mutect2, pindel, varscan2
- NDUFA9 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as COSV56932676; called by muse, mutect2, varscan2
- NEB | c.18388del p.I6130Lfs*13 | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | catalogued as COSV51466788; called by mutect2, pindel, varscan2
- NEUROG1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV59083261; called by muse, mutect2
- NFATC2 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs1340389038, COSV65352912, COSV65354656; called by muse, mutect2, varscan2
- NFKBIZ | c.1694C>A p.A565D | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV58202308; called by muse, mutect2
- NKX6-1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs200051548, COSV55686199; called by muse, mutect2, varscan2
- NLGN2 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV57212593; called by muse, mutect2, varscan2
- NLK | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69409028; called by muse, varscan2
- NOXRED1 | c.131T>C p.F44S | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53629337; called by muse, mutect2, varscan2
- NPPB | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV64687957; called by muse, mutect2, varscan2
- NPTN | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.785); catalogued as rs769814248, COSV54739775; called by muse, mutect2, varscan2
- NR1I3 | c.701C>A p.P234H (on ENST00000367982 / NM_001077480.3; = p.P205H on NM_001077473.3) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV63469702; called by muse, mutect2, varscan2
- NR3C2 | c.1520G>A p.S507N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60993961, COSV61001413; called by muse, mutect2, varscan2
- NUAK1 | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54609338; called by muse, mutect2, varscan2
- OAS1 | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1422237769, COSV52539386; called by muse, mutect2, varscan2
- OR2F1 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as COSV67332194; called by muse, mutect2, varscan2
- OR2G3 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV60682293, COSV60683586; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR3A2 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV68695342; called by muse, mutect2, varscan2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 45/189 reads (24%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR7D4 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs570640089, COSV58073071; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 46/151 reads (30%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- OXER1 | c.1212A>G p.I404M | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54313615; called by muse, mutect2
- OXSM | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55002888; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs763394045; called by mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDHA11 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV56501502, COSV56551821; called by muse, mutect2, varscan2
- PCDHA13 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56507386, COSV99169700; called by muse, mutect2
- PCDHB14 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV53390695; called by muse, mutect2, varscan2
- PCDHB5 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV50677652; called by muse, mutect2, varscan2
- PCDHB9 | c.424del p.I142Yfs*13 | Frame Shift Del (DEL) | VAF 38/185 reads (21%) | catalogued as COSV99505146; called by mutect2, pindel, varscan2
- PCDHGC3 | c.2050del p.R684Gfs*15 | Frame Shift Del (DEL) | VAF 87/389 reads (22%) | catalogued as rs764598056; called by mutect2, pindel, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCF11 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV53527557, COSV53532343; called by muse, mutect2, varscan2
- PDE4DIP | c.1849T>C p.C617R | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.383); catalogued as COSV57734523; called by muse, mutect2, varscan2
- PGR | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.142); catalogued as rs868723861, COSV54803552; called by muse, mutect2, varscan2
- PHF2 | c.2687G>T p.R896M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63684527; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PIK3C2B | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs375521608; called by muse, mutect2, varscan2
- PIK3IP1 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53225133; called by muse, mutect2, varscan2
- PIK3R6 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV61006616; called by muse, mutect2, varscan2
- PIM2 | c.39dup p.G14Rfs*27 | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | catalogued as rs782496935; called by mutect2, pindel, varscan2
- PINK1 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58633338; called by muse, mutect2, varscan2
- PITPNM3 | c.2089A>G p.I697V | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52600960; called by muse, mutect2, varscan2
- PITPNM3 | c.732C>A p.Y244* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV52600972; called by muse, mutect2, varscan2
- PKNOX1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.505); catalogued as rs746447164, COSV52340230; called by muse, mutect2, varscan2
- PLA2R1 | c.4262A>G p.Y1421C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs368059510; called by muse, mutect2, varscan2
- PLCH1 | c.2502T>C p.P834= (on ENST00000340059 / NM_001130960.2; = p.P846= on NM_014996.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/82 reads (17%) | catalogued as COSV58211847; called by muse, mutect2, varscan2
- PLEC | c.8321C>T p.A2774V (on ENST00000322810 / NM_201380.4; = p.A2664V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs782384162, COSV59601081, COSV59700377; ClinVar: uncertain significance; called by muse, varscan2
- PLEKHA8 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 115/412 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs776503360, COSV51656172; called by muse, varscan2
- PLSCR5 | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs369226137; called by muse, mutect2, varscan2
- PLXNB3 | c.2149T>G p.S717A | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV62803152; called by muse, mutect2, varscan2
- POLD1 | c.347del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as COSV101486926; called by mutect2, pindel, varscan2
- POM121L12 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.276); catalogued as rs374755593, COSV68692853, COSV68694663; called by muse, mutect2, varscan2
- PPM1H | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57380427; called by muse, mutect2, varscan2
- PREP | c.55C>T p.R19W (on ENST00000369110; = p.R85W on NM_002726.5) | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1474917244, COSV64872684; called by muse, mutect2, varscan2
- PRSS38 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765433110, COSV64542227; called by muse, mutect2, varscan2
- PSIP1 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV66253598, COSV66255063; called by muse, mutect2, varscan2
- PTGIS | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.052); catalogued as COSV54841321; called by muse, mutect2, varscan2
- PTPN21 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV60852711; called by muse, mutect2, varscan2
- PTPN3 | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV52711959; called by muse, mutect2, varscan2
- PTPRB | c.4346del p.P1449Lfs*9 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1476690081; called by mutect2, pindel, varscan2
- PTPRU | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.197); catalogued as COSV100113696, COSV60538286; called by muse, mutect2, varscan2
- PTX4 | c.1132G>A p.V378M (on ENST00000447419 / NM_001328608.2; = p.V373M on NM_001013658.1) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as rs774104130, COSV53520461; called by mutect2, varscan2
- PZP | c.4428T>C p.D1476= | Splice Region (SNP) | VAF 26/95 reads (27%) | catalogued as rs996836581, COSV54372224; called by muse, mutect2, varscan2
- QRFPR | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 132/524 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57680731; called by muse, mutect2
- R3HDM2 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV60416548; called by muse, mutect2, varscan2
- RABEP2 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs755897586, COSV62868983; called by muse, varscan2
- RALGPS2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as rs943234484, COSV61340428; called by muse, mutect2, varscan2
- RANBP10 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.265); catalogued as rs1402469852, COSV58162159; called by muse, mutect2, varscan2
- RASGRP3 | c.1697T>C p.L566P (on ENST00000402538 / NM_001349975.2; = p.L565P on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.844); catalogued as COSV67825662; called by muse, mutect2, varscan2
- RBBP4 | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65131945; called by muse, mutect2, varscan2
- RBM22 | c.1106del p.P369Lfs*94 | Frame Shift Del (DEL) | VAF 58/207 reads (28%) | catalogued as COSV99555940; called by mutect2, pindel, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 37/120 reads (31%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM28 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746002917, COSV56162615, COSV56163812; called by muse, mutect2, varscan2
- RBM46 | c.1355T>C p.L452S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV55982461; called by muse, mutect2, varscan2
- RERE | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.204); catalogued as rs757157743, COSV61941518; called by muse, mutect2, varscan2
- REST | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV58363286; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS13 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV67346803; called by muse, mutect2, varscan2
- RHBDF1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.112); catalogued as COSV51958558; called by muse, mutect2, varscan2
- RIC8A | c.1066-2A>G p.X356_splice (on ENST00000526104 / NM_001286134.1; = p.Q361R on NM_021932.5) | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV57344528; called by muse, mutect2, varscan2
- RIF1 | c.6664C>T p.R2222W | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752900757, COSV54624351; called by muse, mutect2, varscan2
- RIPK4 | c.1456G>A p.G486S (on ENST00000352483; = p.G438S on NM_020639.3) | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1055788509, COSV60185943; called by muse, mutect2, varscan2
- RNF213 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs148610110; called by muse, mutect2, varscan2
- ROBO4 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.783); catalogued as COSV60628633; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 40/72 reads (56%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUFY1 | c.1957_1959del p.K653del | In Frame Del (DEL) | VAF 27/118 reads (23%) | catalogued as rs777382030; called by mutect2, pindel, varscan2
- RUSC2 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs778441826, COSV63430888; called by muse, mutect2, varscan2
- RYR2 | c.1397del p.P466Qfs*5 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as COSV100771204; called by mutect2, pindel, varscan2
- SALL1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV99192561; called by mutect2, varscan2
- SAT1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63380905; called by muse, mutect2, varscan2
- SBF1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs556200860, COSV62370943; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 56/164 reads (34%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAF1 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1413625348, COSV62183843; called by muse, mutect2, varscan2
- SDK2 | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV101168967; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC31B | c.3490A>C p.M1164L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1162224522, COSV100649158; called by muse, mutect2, varscan2
- SEZ6L2 | c.1856C>T p.P619L (on ENST00000308713 / NM_001114099.3; = p.P549L on NM_012410.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58105187; called by muse, mutect2, varscan2
- SFRP4 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52262371; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs777796332; called by mutect2, varscan2
- SHANK1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs150390491; called by muse, mutect2, varscan2
- SLC12A9 | c.2090T>C p.V697A | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51937762; called by muse, mutect2
- SLC25A21 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100492577, COSV58734954; called by muse, mutect2
- SLC6A16 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs189786711, COSV60031104; called by muse, mutect2, varscan2
- SLC9A7 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV60384458; called by muse, mutect2, varscan2
- SMC1A | c.1211A>G p.Q404R | Missense Mutation (SNP) | VAF 90/452 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV59132379; called by muse, mutect2, varscan2
- SMC6 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs563299750, COSV61179081; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs760667210; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX9 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67586320; called by muse, mutect2
- SOBP | c.2473G>A p.G825S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV58003834; called by muse, mutect2, varscan2
- SOX5 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58625556; called by muse, mutect2, varscan2
- SOX9 | c.916del p.V306Cfs*77 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs1297203260; called by mutect2, pindel, varscan2
- SPANXN3 | c.71del p.N24Mfs*12 | Frame Shift Del (DEL) | VAF 92/404 reads (23%) | catalogued as rs781940283; called by mutect2, varscan2
- SPATS2L | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.43); catalogued as rs754518191, COSV62354422; called by muse, mutect2, varscan2
- SPEG | c.5263T>C p.Y1755H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV56681659; called by muse, mutect2, varscan2
- SPG7 | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.96); catalogued as COSV51955502; called by muse, mutect2, varscan2
- SPTB | c.3301C>T p.Q1101* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV67635734; called by muse, mutect2, varscan2
- SPTBN4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405467847, COSV58960792; called by muse, mutect2, varscan2
- SPTBN5 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs374190044; called by muse, mutect2, varscan2
- SPTLC2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53639235, COSV53643781; called by muse, mutect2, varscan2
- SRM | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV65385051; called by muse, mutect2, varscan2
- SRP72 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61379569; called by muse, mutect2, varscan2
- STAB2 | c.7403T>C p.I2468T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66348643; called by muse, mutect2, varscan2
- STAU2 | c.1091dup p.N364Kfs*13 (on ENST00000524300 / NM_001164380.2; = p.N332Kfs*13 on NM_014393.2) | Frame Shift Ins (INS) | VAF 32/172 reads (19%) | catalogued as rs746501298; called by mutect2, varscan2
- STRC | c.461del p.P154Lfs*30 | Frame Shift Del (DEL) | VAF 17/146 reads (12%) | catalogued as rs1411667337; called by mutect2, pindel
- SYNE2 | c.7246T>C p.S2416P | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV59973824; called by muse, mutect2, varscan2
- TAAR1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs753568048, COSV51589660; called by muse, mutect2, varscan2
- TADA2B | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV53828517; called by muse, mutect2
- TAF1 | c.1790G>A p.R597H (on ENST00000373790 / NM_138923.4; = p.R618H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs143439292, COSV52114051; called by muse, mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | catalogued as rs750181498; called by mutect2, varscan2
- TATDN2 | c.1587A>T p.E529D | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV55054590; called by muse, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs757209781; called by mutect2, pindel, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 40/166 reads (24%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TCF7L2 | c.1755del p.S586Pfs*33 (on ENST00000355995 / NM_001367943.1; = p.S563Pfs*33 on NM_030756.5) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs1189031682; called by mutect2, pindel, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENM2 | c.6050A>G p.Q2017R (on ENST00000518659 / NM_001122679.2; = p.Q1778R on NM_001080428.3) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69144177; called by muse, mutect2, varscan2
- TERF2 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54749538; called by muse, mutect2, varscan2
- TIAM1 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54579194; called by muse, mutect2, varscan2
- TICRR | c.5072C>T p.A1691V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749490163, COSV51547881; called by muse, mutect2, varscan2
- TLR3 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV57170804; called by muse, mutect2, varscan2
- TLR8 | c.3085C>T p.R1029W (on ENST00000218032 / NM_138636.5; = p.R1047W on NM_016610.4) | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54320284; called by muse, mutect2, varscan2
- TLR9 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1366842587, COSV59727937; called by muse, mutect2, varscan2
- TMBIM4 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV53971184; called by muse, mutect2, varscan2
- TMCO3 | c.1539+2T>C p.X513_splice | Splice Site (SNP) | VAF 47/132 reads (36%) | catalogued as COSV64809631; called by muse, mutect2, varscan2
- TMEM132E | c.2123G>A p.R708H (on ENST00000321639; = p.R798H on NM_001304438.2) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58700935; called by muse, mutect2, varscan2
- TMEM273 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV65154277; called by muse, mutect2, varscan2
- TMEM45B | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55655824; called by muse, mutect2, varscan2
- TMEM87B | c.453T>C p.N151= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs141654814; called by muse, mutect2, varscan2
- TMPRSS7 | c.947G>A p.S316N (on ENST00000452346; = p.S190N on NM_001042575.2) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV69979762; called by muse, mutect2, varscan2
- TNKS2 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV65417255; called by muse, mutect2, varscan2
- TNPO2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs751866827, COSV63509392; called by muse, varscan2
- TNS3 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1334788076, COSV100235663, COSV60800954; called by muse, mutect2, varscan2
- TRIM10 | c.138A>G p.I46M | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.603); catalogued as COSV64990669; called by muse, mutect2, varscan2
- TRIM9 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs765465611, COSV53617243; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs752676391; called by mutect2, varscan2
- TRMT10A | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs748257023, COSV56746298; called by muse, mutect2, varscan2
- TROAP | c.1538A>G p.Q513R | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV57746342; called by muse, mutect2, varscan2
- TSPOAP1 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201092790, COSV52105305; called by muse, mutect2, varscan2
- TTF2 | c.2420A>G p.E807G | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65634031; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.101237C>T p.S33746L (on ENST00000591111; = p.S26322L on NM_003319.4) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | PolyPhen benign (0.087); catalogued as COSV60405966; called by muse, mutect2, varscan2
- UBE2T | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as rs767502640, COSV66153627; called by muse, mutect2, varscan2
- UBE3B | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs530625803, COSV61078373; called by muse, mutect2, varscan2
- UCK1 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV61228062; called by muse, mutect2, varscan2
- UFL1 | c.1129del p.R377Vfs*3 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | catalogued as rs757217801, COSV65149363; called by mutect2, pindel, varscan2
- UPF2 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV62664588; called by muse, mutect2, varscan2
- USP14 | c.1361A>C p.K454T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV55277959; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs572063854; called by mutect2, varscan2
- UTP25 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.909); catalogued as COSV72227544; called by muse, mutect2, varscan2
- UVRAG | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs376568898, COSV62107661; called by muse, mutect2, varscan2
- VCPIP1 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.914); catalogued as COSV60050453; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs748321397; called by mutect2, varscan2
- VPS37A | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV61353609; called by muse, mutect2, varscan2
- WDR6 | c.2421del p.R808Gfs*33 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs750038548, COSV58247104; called by mutect2, pindel, varscan2
- WDR62 | c.692A>G p.E231G | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV54340440; called by muse, mutect2, varscan2
- WDR62 | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.492); catalogued as rs542711912, COSV54340465; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WNK4 | c.1866T>C p.A622= | Splice Region (SNP) | VAF 150/522 reads (29%) | catalogued as COSV55911335; called by muse, mutect2, varscan2
- WNT11 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201232636, COSV59445050; called by muse, mutect2, varscan2
- XIRP2 | c.1787G>A p.R596Q (on ENST00000628543; = p.R771Q on NM_152381.6) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748922110, COSV54740369; called by muse, mutect2, varscan2
- XKR4 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 139/235 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs886369114, COSV59302757, COSV59335594; called by muse, mutect2, varscan2
- XPNPEP2 | c.1359dup p.Q454Afs*35 | Frame Shift Ins (INS) | VAF 68/186 reads (37%) | catalogued as rs762212384; called by mutect2, pindel, varscan2
- ZBTB4 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.114); catalogued as rs772776788, COSV60976640; called by muse, mutect2, varscan2
- ZBTB45 | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63525534; called by muse, mutect2, varscan2
- ZC3H18 | c.2406del p.Q804Sfs*15 | Frame Shift Del (DEL) | VAF 61/267 reads (23%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZFHX4 | c.5117C>A p.A1706D | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50511844, COSV51501409; called by muse, mutect2, varscan2
- ZFYVE26 | c.5690C>T p.S1897L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs752859634, COSV61324934; called by muse, mutect2, varscan2
- ZIC1 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1335188281, COSV51551824, COSV51558768; called by muse, mutect2, varscan2
- ZMYND11 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV59082888; called by muse, mutect2, varscan2
- ZNF215 | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV53495577; called by muse, mutect2, varscan2
- ZNF285 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.273); catalogued as rs773164147, COSV58411711; called by muse, mutect2, varscan2
- ZNF407 | c.6664G>A p.V2222M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761613021, COSV55274245; called by muse, mutect2, varscan2
- ZNF571 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60734998; called by muse, mutect2, varscan2
- ZNF582 | c.767A>C p.E256A | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV56734046; called by muse, mutect2, varscan2
- ZNF608 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1359015505, COSV100102621; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 94/280 reads (34%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF775 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61613172; called by muse, mutect2, varscan2
- ZNF862 | c.346A>G p.S116G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1476404237, COSV56226689; called by muse, mutect2, varscan2
- ZNFX1 | c.3586C>A p.L1196I | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as rs781451100, COSV65602561; called by muse, mutect2, varscan2
- ZW10 | c.591T>G p.S197R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV52320128; called by muse, mutect2, varscan2
- ZYX | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV59557956; called by muse, mutect2, varscan2
- ABCB4 | c.3653del p.K1218Rfs*18 (on ENST00000265723 / NM_018849.3; = p.K1211Rfs*18 on NM_000443.4) | Frame Shift Del (DEL) | VAF 97/330 reads (29%) | called by mutect2, pindel, varscan2
- AMOTL1 | c.335del p.P112Qfs*5 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.1752del p.F584Lfs*64 (on ENST00000395184 / NM_001025616.3; = p.F491Lfs*64 on NM_031305.3) | Frame Shift Del (DEL) | VAF 36/157 reads (23%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.2488del p.E830Nfs*19 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- ARID1A | c.4403del p.P1468Lfs*13 | Frame Shift Del (DEL) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 60/215 reads (28%) | called by mutect2, pindel, varscan2
- ARL13B | c.932dup p.N311Kfs*2 (on ENST00000394222 / NM_001174150.2; = p.N204Kfs*2 on NM_144996.4) | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, varscan2
- ATP2B4 | c.261del p.K89Sfs*6 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- ATP6V1A | c.981_984del p.Y328Lfs*18 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- B4GALT1 | c.954del p.F318Lfs*4 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- C11orf53 | c.273del p.K92Sfs*34 | Frame Shift Del (DEL) | VAF 84/346 reads (24%) | called by mutect2, pindel, varscan2
- CCDC9B | c.942dup p.A315Sfs*51 | Frame Shift Ins (INS) | VAF 27/111 reads (24%) | called by mutect2, pindel, varscan2
- CEP44 | c.22del p.R8Efs*6 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- COBL | c.121del p.H41Tfs*14 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, varscan2
- COL19A1 | c.474del p.F158Lfs*34 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | called by mutect2, pindel, varscan2
- COL5A1 | c.1502dup p.G502Wfs*114 | Frame Shift Ins (INS) | VAF 29/127 reads (23%) | called by mutect2, pindel, varscan2
- CTPS2 | c.151del p.S51Hfs*11 | Frame Shift Del (DEL) | VAF 52/369 reads (14%) | called by mutect2, pindel, varscan2
- CUBN | c.3737del p.P1246Lfs*12 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel, varscan2
- DAG1 | c.749del p.K250Rfs*17 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, pindel, varscan2
- DDX17 | c.361_362dup p.W122Sfs*4 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | called by mutect2, pindel, varscan2
- EHMT1 | c.2919_2920del p.E973Dfs*203 | Frame Shift Del (DEL) | VAF 25/141 reads (18%) | called by pindel, varscan2
- EPOR | c.1293del p.S432Afs*21 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- ESCO1 | c.55del p.S19Vfs*17 | Frame Shift Del (DEL) | VAF 36/133 reads (27%) | called by mutect2, pindel, varscan2
- EXOC6 | c.393del p.K131Nfs*9 | Frame Shift Del (DEL) | VAF 52/192 reads (27%) | called by mutect2, pindel, varscan2
- FANCD2 | c.486del p.F162Lfs*19 | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- FCGBP | c.12103_12104del p.V4035Pfs*11 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by pindel, varscan2
- FIBP | c.570del p.K190Nfs*5 | Frame Shift Del (DEL) | VAF 65/210 reads (31%) | called by mutect2, pindel, varscan2
- FLG | c.8003C>T p.S2668L | Missense Mutation (SNP) | VAF 77/648 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FMN2 | c.4243del p.I1415* | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- GDF10 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- HLA-B | c.1079_1080del p.L360Hfs*39 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by pindel, varscan2
- HS3ST5 | c.1006del p.Y336Tfs*8 | Frame Shift Del (DEL) | VAF 48/164 reads (29%) | called by mutect2, pindel, varscan2
- IGFN1 | c.2003del p.P668Qfs*9 (on ENST00000295591 / NM_001367841.1; = p.P3125Qfs*9 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ILF2 | c.1093_1095del p.K365del | In Frame Del (DEL) | VAF 36/102 reads (35%) | called by pindel, varscan2
- INTS1 | c.2992C>T p.L998F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- JADE1 | c.1180del p.R394Gfs*20 | Frame Shift Del (DEL) | VAF 45/211 reads (21%) | called by mutect2, pindel, varscan2
- JARID2 | c.2921del p.P974Qfs*11 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- KCTD9 | c.626del p.L209Cfs*2 | Frame Shift Del (DEL) | VAF 62/246 reads (25%) | called by mutect2, pindel, varscan2
- KDM6A | c.2717del p.N906Mfs*31 | Frame Shift Del (DEL) | VAF 61/150 reads (41%) | called by mutect2, pindel, varscan2
- KIF20B | c.4399del p.M1467* (on ENST00000371728 / NM_001284259.2; = p.M1427* on NM_016195.4) | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- KIF21A | c.387del p.K129Nfs*3 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, varscan2
- KMT2D | c.5058del p.K1686Nfs*36 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | called by mutect2, varscan2
- LCE2B | c.323del p.G108Afs*7 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- LRFN3 | c.1277del p.P426Lfs*8 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | called by mutect2, pindel, varscan2
- LUZP1 | c.2095dup p.A699Gfs*3 | Frame Shift Ins (INS) | VAF 209/777 reads (27%) | called by mutect2, pindel, varscan2
- LYST | c.377_380del p.G126Vfs*11 | Frame Shift Del (DEL) | VAF 39/177 reads (22%) | called by pindel, varscan2
- LZTS1 | c.765del p.I256Sfs*98 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- MED12L | c.417del p.E140Rfs*7 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- MED23 | c.3321_3324delinsG p.T1108del | In Frame Del (DEL) | VAF 40/122 reads (33%) | called by pindel, varscan2*
- MGRN1 | c.232del p.H78Tfs*4 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- MSANTD3 | c.721del p.M241Wfs*44 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- NES | c.3745del p.V1249Cfs*11 | Frame Shift Del (DEL) | VAF 68/292 reads (23%) | called by mutect2, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 80/388 reads (21%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, varscan2
- NTRK1 | c.1753del p.L585Cfs*73 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- OR10H1 | c.944del p.N315Mfs*2 | Frame Shift Del (DEL) | VAF 39/151 reads (26%) | called by mutect2, pindel, varscan2
- OR2T4 | c.803del p.K268Rfs*10 | Frame Shift Del (DEL) | VAF 53/146 reads (36%) | called by mutect2, varscan2
- PDE3A | c.511del p.E171Kfs*36 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- PKP3 | c.1366del p.L456Cfs*191 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- POLB | c.383del p.N128Mfs*5 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- PPP1CC | c.905del p.K302Rfs*9 | Frame Shift Del (DEL) | VAF 96/291 reads (33%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 81/412 reads (20%) | called by mutect2, pindel, varscan2
- PPP2R3C | c.413del p.F138Sfs*28 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel
- PRICKLE4 | c.211del p.V71* (on ENST00000359201; = p.V111* on NM_013397.6) | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- PSMA6 | c.546del p.V183* | Frame Shift Del (DEL) | VAF 62/249 reads (25%) | called by mutect2, varscan2
- PSMC3 | c.1180del p.A394Pfs*12 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | called by mutect2, pindel, varscan2
- PSMC6 | c.1161del p.V388Wfs*20 (on ENST00000612399; = p.V374Wfs*20 on NM_002806.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- PSMD7 | c.209del p.L70* | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- PTCD3 | c.936del p.K312Nfs*9 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- PTGFRN | c.366del p.S123Afs*35 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- RASA1 | c.422dup p.Y142Lfs*16 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- RFX3 | c.971dup p.L324Ffs*14 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, pindel, varscan2
- RNF111 | c.2318del p.P773Hfs*44 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, pindel
- RP1 | c.2377del p.R793Efs*55 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- RPS11 | c.91_93del p.E31del | In Frame Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- RPS20 | c.25del p.T9Hfs*16 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- RRN3 | c.1167del p.K389Nfs*34 | Frame Shift Del (DEL) | VAF 81/318 reads (25%) | called by mutect2, pindel, varscan2
- S100A8 | c.256del p.S86Afs*10 | Frame Shift Del (DEL) | VAF 65/241 reads (27%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, varscan2
- SCAF11 | c.4382del p.N1461Tfs*2 | Frame Shift Del (DEL) | VAF 78/344 reads (23%) | called by mutect2, pindel, varscan2
- SCN11A | c.1035del p.F345Lfs*11 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- SDC3 | c.517dup p.D173Gfs*97 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- SEPTIN6 | c.1014del p.E339Kfs*4 | Frame Shift Del (DEL) | VAF 178/874 reads (20%) | called by mutect2, pindel, varscan2
- SETX | c.5243del p.F1748Sfs*3 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- SLC4A1 | c.515dup p.V173Cfs*30 | Frame Shift Ins (INS) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- SLC4A1AP | c.459del p.Y154Tfs*16 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- SLIT1 | c.2180del p.G727Afs*65 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- SPEN | c.1201_1202del p.F401Lfs*6 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | called by mutect2, pindel, varscan2
- ST3GAL4 | c.327del p.K110Rfs*38 (on ENST00000392669 / NM_001254758.1; = p.K106Rfs*38 on NM_006278.3) | Frame Shift Del (DEL) | VAF 72/371 reads (19%) | called by mutect2, pindel, varscan2
- STT3A | c.374_376del p.S125del | In Frame Del (DEL) | VAF 30/112 reads (27%) | called by pindel, varscan2
- TAF15 | c.1589del p.G530Afs*116 (on ENST00000605844 / NM_139215.3; = p.G527Afs*116 on NM_003487.4) | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- TAF2 | c.1810del p.I604Sfs*3 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- TAF3 | c.1638del p.D547Tfs*13 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- TAS1R3 | c.65del p.P22Hfs*10 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- TCP11 | c.314dup p.D106* (on ENST00000512012; = p.D44* on NM_018679.5) | Frame Shift Ins (INS) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- TLCD3B | c.28del p.V10Wfs*112 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel
- TMEM119 | c.227del p.G76Afs*12 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- TXNDC17 | c.17_19del p.E6del | In Frame Del (DEL) | VAF 7/24 reads (29%) | called by pindel, varscan2
- UNC45A | c.1596-5_1603delinsGG p.X532_splice | Splice Site (DEL) | VAF 31/144 reads (22%) | called by pindel, varscan2*
- USP19 | c.1145del p.G382Afs*35 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- WAPL | c.557dup p.N186Kfs*3 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- WDFY3 | c.5525dup p.L1842Ffs*52 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 105/409 reads (26%) | called by mutect2, pindel, varscan2
- ZNF131 | c.1158del p.G387Efs*26 (on ENST00000509156 / NM_001330707.2; = p.G353Efs*26 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- ZNF148 | c.852dup p.L285Tfs*3 | Frame Shift Ins (INS) | VAF 46/172 reads (27%) | called by mutect2, pindel, varscan2
- ZNF669 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, varscan2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by mutect2, varscan2
- ABCA4 | c.3798C>T p.D1266= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as COSV64679394; called by muse, mutect2, varscan2
- AC126283.2 | c.777C>T p.C259= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV67100194; called by muse, mutect2, varscan2
- ACSF2 | c.711C>T p.S237= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV51974578; called by muse, mutect2, varscan2
- ADCY9 | c.3351G>A p.A1117= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs371159341; called by muse, mutect2, varscan2
- ADGRE3 | c.1848C>T p.I616= | Silent (SNP) | VAF 72/259 reads (28%) | catalogued as rs147270469, COSV53729101; called by muse, mutect2, varscan2
- ADGRG1 | c.723G>A p.Q241= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV101113609; called by muse, mutect2, varscan2
- AMACR | c.429G>A p.P143= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs368427062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.774G>A p.A258= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs146748344; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP3B2 | c.2766C>T p.G922= (on ENST00000261722; = p.G916= on NM_004644.5) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55615662; called by muse, mutect2, varscan2
- ARFGAP3 | c.531A>G p.S177= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV54315047; called by muse, mutect2, varscan2
- ARHGAP4 | c.2070G>A p.Q690= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV61687113; called by muse, mutect2, varscan2
- ATP2B3 | c.1011G>A p.A337= | Silent (SNP) | VAF 99/195 reads (51%) | catalogued as rs142541769, COSV54852162; called by muse, mutect2, varscan2
- BBOF1 | c.*2_*4del | Silent (DEL) | VAF 39/172 reads (23%) | called by mutect2, pindel, varscan2
- BCORL1 | c.1203G>A p.T401= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs779766420, COSV54395082; called by muse, mutect2, varscan2
- C19orf47 | c.273C>T p.G91= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs750933756, COSV63508375; called by muse, mutect2, varscan2
- C2orf42 | c.1323G>T p.L441= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as COSV52453338; called by muse, mutect2, varscan2
- CCAR1 | c.2181G>A p.P727= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs149316365; called by muse, mutect2, varscan2
- CCDC62 | c.480G>A p.T160= | Silent (SNP) | VAF 59/191 reads (31%) | catalogued as rs776433830, COSV53437914; called by muse, mutect2, varscan2
- CDC123 | c.927C>T p.D309= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV55400498; called by muse, mutect2, varscan2
- CECR2 | c.1956A>G p.V652= (on ENST00000342247 / NM_001290047.2; = p.V469= on NM_001290046.1) | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs777023982, COSV52850047; called by muse, mutect2, varscan2
- CEND1 | c.153G>A p.P51= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs767548322, COSV100204348; called by muse, mutect2, varscan2
- CHRDL2 | c.423C>T p.C141= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1359100053, COSV55225732; called by muse, mutect2, varscan2
- CHRNB2 | c.426C>T p.S142= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV63809652; called by muse, mutect2, varscan2
- CLDN9 | c.510G>T p.A170= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV60911870; called by muse, mutect2, varscan2
- COG3 | c.1671G>A p.T557= | Silent (SNP) | VAF 85/249 reads (34%) | catalogued as rs756431240, COSV63075571; called by muse, mutect2, varscan2
- COL12A1 | c.4794T>C p.V1598= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as COSV59410421; called by muse, mutect2, varscan2
- CPE | c.546C>T p.A182= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as rs1297353438, COSV68582475; called by muse, varscan2
- DAB2IP | c.2448G>A p.A816= (on ENST00000408936; = p.A788= on NM_032552.3) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs777515218, COSV52269876; called by muse, mutect2, varscan2
- DAG1 | c.933G>A p.R311= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV58187906; called by muse, mutect2
- DGKA | c.501T>C p.I167= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV59389188; called by muse, mutect2
- DLGAP4 | c.21C>T p.S7= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59424662; called by muse, mutect2
- DNAH12 | c.717T>C p.I239= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV60859220; called by muse, mutect2, varscan2
- DNAH2 | c.4263C>A p.A1421= | Silent (SNP) | VAF 86/253 reads (34%) | catalogued as COSV66728721; called by muse, mutect2, varscan2
- DNAH9 | c.1081C>T p.L361= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV52381490; called by muse, mutect2, varscan2
- DOCK8 | c.1098G>A p.T366= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs139297216, COSV101210329; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DOCK8 | c.3639C>T p.A1213= | Silent (SNP) | VAF 94/277 reads (34%) | catalogued as COSV66624559; called by muse, mutect2, varscan2
- ELANE | c.120G>A p.A40= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1331769113, COSV52256528; called by muse, mutect2, varscan2
- EPHA10 | c.807C>T p.C269= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV57627871; called by muse, mutect2, varscan2
- F10 | c.204C>T p.R68= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as rs376704564; called by muse, mutect2, varscan2
- FAM167A | c.438C>T p.G146= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs761556428, COSV52670437; called by muse, mutect2, varscan2
- FCGBP | c.6903C>T p.G2301= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as COSV99664630; called by muse, mutect2, varscan2
- FSTL4 | c.1188C>T p.S396= | Silent (SNP) | VAF 47/186 reads (25%) | catalogued as rs752516846, COSV54786807; called by muse, mutect2, varscan2
- GIT2 | c.2220C>T p.Y740= (on ENST00000355312 / NM_057169.5; = p.Y662= on NM_014776.5) | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs150244358; called by muse, varscan2
- GOSR1 | c.303T>C p.N101= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as COSV56721226; called by muse, mutect2, varscan2
- GPATCH2L | c.696T>C p.T232= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs375395620; called by muse, mutect2, varscan2
- GPR61 | c.183C>T p.A61= | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as rs766429683, COSV68178295; called by muse, mutect2, varscan2
- GUCA1C | c.435C>T p.N145= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV53757131; called by muse, mutect2, varscan2
- H4C6 | c.270G>A p.A90= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV66685839; called by muse, mutect2, varscan2
- HDAC7 | c.1746T>C p.S582= (on ENST00000427332; = p.S621= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV50410913; called by muse, mutect2, varscan2
- HEG1 | c.2331C>T p.D777= | Silent (SNP) | VAF 87/289 reads (30%) | catalogued as COSV60766258; called by muse, mutect2, varscan2
- HS3ST3A1 | c.828G>A p.A276= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs548851130, COSV99404600; called by mutect2, varscan2
- IGF2BP2 | c.507C>A p.A169= | Silent (SNP) | VAF 10/173 reads (6%) | catalogued as COSV60492503; called by muse, mutect2
- IL4I1 | c.829C>T p.L277= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV55581765; called by muse, mutect2, varscan2
- ILK | c.771C>T p.C257= | Silent (SNP) | VAF 67/207 reads (32%) | catalogued as rs1292717719, COSV54992980; called by muse, mutect2, varscan2
- INPP4B | c.1302T>C p.S434= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as COSV53749428; called by muse, mutect2, varscan2
- JMJD4 | c.1117A>C p.R373= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV59920665; called by muse, mutect2, varscan2
- KCNA6 | c.33G>A p.A11= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV54978503, COSV99768319; called by muse, mutect2, varscan2
- KDM3A | c.735C>T p.H245= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs755089864, COSV57221620; called by muse, mutect2, varscan2
- KLHL20 | c.672C>T p.N224= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs559139059, COSV52942114, COSV52945694; called by muse, mutect2, varscan2
- LRIT2 | c.330G>A p.L110= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as COSV64520082; called by muse, mutect2, varscan2
- MAG | c.1026G>A p.T342= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs200660504, COSV62700616; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3816G>A p.S1272= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs766380329, COSV51603298; called by muse, mutect2, varscan2
- MCHR2 | c.1023G>A p.*341= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV56009842, COSV99912768; called by muse, mutect2, varscan2
- MCM6 | c.2217C>T p.D739= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as rs774404951, COSV51467764; called by muse, mutect2, varscan2
- MED12L | c.3792T>C p.P1264= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV56400900; called by muse, mutect2, varscan2
- MEPCE | c.807C>T p.H269= | Silent (SNP) | VAF 69/228 reads (30%) | catalogued as COSV52770203; called by muse, mutect2, varscan2
- METRN | c.729C>T p.G243= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs377567346; called by muse, mutect2, varscan2
- MLIP | c.1194G>A p.L398= | Silent (SNP) | VAF 142/299 reads (47%) | catalogued as COSV51438924; called by muse, mutect2, varscan2
- MTNR1B | c.63C>T p.G21= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57069473; called by muse, mutect2, varscan2
- NID2 | c.3447C>T p.Y1149= | Silent (SNP) | VAF 91/314 reads (29%) | catalogued as rs756293649, COSV53504060; called by muse, mutect2, varscan2
- NOM1 | c.2484C>T p.N828= | Silent (SNP) | VAF 81/280 reads (29%) | catalogued as rs371215482, COSV51980261; called by muse, mutect2, varscan2
- NOX1 | c.1620G>A p.L540= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV54197145; called by muse, mutect2, varscan2
- NR4A2 | c.258G>A p.Q86= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV59896008; called by muse, mutect2, varscan2
- NRAP | c.3966C>A p.P1322= (on ENST00000359988 / NM_001322945.2; = p.P1287= on NM_006175.4) | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV100748307, COSV63494679; called by muse, mutect2, varscan2
- OBSCN | c.2382C>T p.L794= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs370849282, COSV52754527; called by muse, mutect2, varscan2
- OBSL1 | c.4476C>T p.H1492= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs753077363, COSV54711190; called by muse, mutect2, varscan2
- OR10C1 | c.801C>T p.Y267= (on ENST00000622521; = p.Y265= on NM_013941.3) | Silent (SNP) | VAF 118/278 reads (42%) | catalogued as rs753327604, COSV65822313, COSV65824117, COSV99058448; called by muse, mutect2, varscan2
- ORC5 | c.147G>A p.T49= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs142978774; called by muse, mutect2, varscan2
- OTUD6A | c.654C>T p.G218= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs757343993, COSV57974584; called by muse, mutect2, varscan2
- PCDHA3 | c.1671C>T p.D557= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as rs199682432, COSV63539775; called by muse, mutect2, varscan2
- PCDHB16 | c.1383C>T p.R461= | Silent (SNP) | VAF 46/214 reads (21%) | catalogued as rs782323992, COSV53369595; called by muse, mutect2, varscan2
- PCDHB3 | c.1797C>T p.N599= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV99164147; called by muse, mutect2, varscan2
- PCDHGA3 | c.654C>T p.G218= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1047556381, COSV54051725; called by muse, mutect2, varscan2
- PCDHGA3 | c.1059A>G p.T353= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV54051753; called by muse, mutect2, varscan2
- PDZD11 | c.9C>T p.S3= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV52105573; called by muse, mutect2, varscan2
- PFKP | c.1317C>T p.D439= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs148946725; called by muse, mutect2, varscan2
- PI4KB | c.42T>G p.T14= (on ENST00000368873 / NM_001369623.1; = p.T26= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV55022357; called by muse, mutect2, varscan2
- PLXDC2 | c.258T>C p.S86= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV65924530; called by muse, mutect2, varscan2
- PMP22 | c.324G>A p.L108= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs768210658, COSV56603699; called by muse, mutect2, varscan2
- PSMD7 | c.645C>T p.V215= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs368732606; called by muse, mutect2, varscan2
- PUS7L | c.849A>G p.K283= | Silent (SNP) | VAF 84/318 reads (26%) | catalogued as COSV61263162; called by muse, mutect2, varscan2
- R3HDM1 | c.789T>C p.F263= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV51534298; called by muse, mutect2, varscan2
- RBL2 | c.1014T>C p.Y338= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV50891368; called by muse, mutect2, varscan2
- RELN | c.1746G>A p.T582= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs138532222, COSV59035506; called by muse, mutect2, varscan2
- RIBC2 | c.603G>A p.K201= | Silent (SNP) | VAF 18/447 reads (4%) | catalogued as COSV61582463; called by muse, mutect2
- RYR1 | c.7161C>T p.S2387= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs766839127, COSV62113457; ClinVar: likely benign; called by muse, mutect2
- S100A8 | c.24C>A p.A8= | Silent (SNP) | VAF 86/299 reads (29%) | catalogued as COSV64198307; called by muse, mutect2, varscan2
- SCAMP5 | c.258C>T p.Y86= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs373424946; called by muse, mutect2, varscan2
- SESN3 | c.495A>G p.R165= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV53587242, COSV53587942; called by muse, mutect2, varscan2
- SETBP1 | c.2613T>C p.I871= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56339481; called by muse, mutect2, varscan2
- SETD1A | c.3141C>G p.S1047= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV52686707, COSV52693197; called by muse, mutect2, varscan2
- SH2D3C | c.2277A>G p.P759= (on ENST00000314830 / NM_170600.3; = p.P602= on NM_005489.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59130863; called by muse, mutect2
- SH2D7 | c.981C>A p.T327= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV51950379; called by muse, mutect2, varscan2
- SH3PXD2A | c.2697C>T p.N899= (on ENST00000369774 / NM_001365079.1; = p.N871= on NM_014631.2) | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs1342229195, COSV60121218; called by muse, mutect2, varscan2
- SLC16A4 | c.912T>C p.F304= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV63917537; called by muse, mutect2, varscan2
- SLC18A1 | c.1071T>C p.G357= | Silent (SNP) | VAF 68/299 reads (23%) | catalogued as COSV52351707; called by muse, mutect2, varscan2
- SLC29A2 | c.597C>A p.P199= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2
- SLC5A10 | c.1710C>T p.H570= (on ENST00000395645 / NM_001042450.4; = p.H586= on NM_152351.5) | Silent (SNP) | VAF 65/257 reads (25%) | catalogued as rs376266996; called by muse, mutect2, varscan2
- SLFNL1 | c.768C>T p.G256= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV57235910; called by muse, mutect2, varscan2
- SMARCD3 | c.1065G>A p.T355= (on ENST00000262188 / NM_001003801.2; = p.T342= on NM_003078.4) | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1050109, COSV50404267; called by muse, mutect2, varscan2
- SPARCL1 | c.1035C>T p.G345= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs373342606; called by muse, mutect2, varscan2
- SPECC1L | c.1041T>C p.S347= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs200756643, COSV58662679; called by muse, mutect2, varscan2
- SRCAP | c.1824G>A p.T608= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as rs770822362, COSV52682660; called by muse, varscan2
- STK17A | c.1152T>A p.S384= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV60049025; called by muse, mutect2, varscan2
- SUN1 | c.711G>A p.S237= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs773413533, COSV100568631; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1860C>A p.A620= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- SVIL | c.3366C>T p.S1122= (on ENST00000355867 / NM_021738.3; = p.S696= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV63449224; called by muse, mutect2, varscan2
- TBCD | c.228G>A p.P76= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs752972547, COSV62809142; called by muse, mutect2, varscan2
- TCERG1 | c.678G>A p.Q226= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs779390603, COSV57042967; called by mutect2, varscan2
- TIE1 | c.711C>T p.C237= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as rs1354210634, COSV65251255; called by muse, mutect2, varscan2
- TMEM147 | c.558C>T p.F186= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs773093757, COSV52867022; called by muse, mutect2, varscan2
- TMEM177 | c.168G>A p.P56= | Silent (SNP) | VAF 101/344 reads (29%) | catalogued as rs116090839, COSV55608476; called by muse, mutect2, varscan2
- TMEM270 | c.300T>C p.A100= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV57640053; called by muse, mutect2, varscan2
- TRO | c.3732T>C p.G1244= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV51509098; called by muse, mutect2, varscan2
- TRPM4 | c.1311G>T p.R437= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV53269736; called by muse, mutect2, varscan2
- TRRAP | c.9270A>G p.A3090= (on ENST00000359863 / NM_001244580.1; = p.A3061= on NM_003496.3) | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV62856234; called by muse, mutect2, varscan2
- TTN | c.24849C>T p.F8283= (on ENST00000591111; = p.F7356= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1215707268, COSV60246938; called by muse, varscan2
- TTN | c.159C>T p.G53= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1367693905, COSV60406020; ClinVar: uncertain significance; called by muse, varscan2
- TUBA3D | c.369C>T p.R123= | Silent (SNP) | VAF 65/239 reads (27%) | catalogued as COSV58313632; called by muse, mutect2, varscan2
- TYW1 | c.1725G>A p.T575= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV62756569; called by muse, mutect2, varscan2
- UBQLNL | c.1206T>A p.S402= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV66494849; called by muse, mutect2, varscan2
- UHRF1 | c.843G>A p.E281= (on ENST00000612630 / NM_001290050.1; = p.E294= on NM_013282.4) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53577414; called by muse, mutect2, varscan2
- UNC93A | c.981G>A p.A327= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs753203183, COSV57809171; called by muse, mutect2, varscan2
- USP34 | c.9936A>G p.L3312= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV63725175; called by muse, mutect2
- VCL | c.3303T>C p.S1101= (on ENST00000211998 / NM_014000.3; = p.S1033= on NM_003373.4) | Silent (SNP) | VAF 84/238 reads (35%) | catalogued as COSV53015564; called by muse, mutect2, varscan2
- WTIP | c.1168C>T p.L390= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs370782319; called by muse, mutect2, varscan2
- ZC3H4 | c.2943C>T p.P981= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as rs201502446; called by muse, mutect2, varscan2
- ZNF236 | c.4710G>A p.T1570= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs531156395, COSV53499985; called by muse, mutect2, varscan2
- ZNF280C | c.624C>T p.G208= | Silent (SNP) | VAF 50/234 reads (21%) | catalogued as COSV63970149; called by muse, varscan2
- ZNF365 | c.669C>T p.D223= | Silent (SNP) | VAF 74/218 reads (34%) | catalogued as rs150802191, COSV67925777; called by muse, mutect2, varscan2
- AGFG2 | c.*1C>T | 3'UTR (SNP) | VAF 91/340 reads (27%) | catalogued as COSV99499639; called by muse, mutect2, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 5/8 reads (63%) | catalogued as rs764079139; called by mutect2, varscan2
- MICAL3 | c.2242-777A>G | Intron (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99263254; called by muse, mutect2, varscan2
- MIR633 | n.15T>A | RNA (SNP) | VAF 8/36 reads (22%) | catalogued as rs1031261252; called by muse, mutect2, varscan2
- NACA | c.70+3907A>G | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as rs1308898880, COSV100771771; called by muse, mutect2, varscan2
- NACA | c.70+3261A>G | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs773945190, COSV100771773; called by muse, mutect2, varscan2
- PDP1 | c.-2C>T | 5'UTR (SNP) | VAF 90/177 reads (51%) | catalogued as COSV99893093; called by muse, mutect2, varscan2
- RUSC1 | c.1358-373T>C | Intron (SNP) | VAF 16/58 reads (28%) | catalogued as rs781275880, COSV99430427; called by muse, varscan2
- SNORD114-15 | n.26G>A | RNA (SNP) | VAF 53/181 reads (29%) | catalogued as rs752195009; called by muse, mutect2, varscan2
- SNORD115-21 | n.6G>A | RNA (SNP) | VAF 121/380 reads (32%) | catalogued as rs779802616; called by muse, mutect2, varscan2
- TEX11 | c.-56del | 5'UTR (DEL) | VAF 34/124 reads (27%) | catalogued as rs772853520, COSV65467559; called by mutect2, varscan2
- VN1R10P | n.710C>T | RNA (SNP) | VAF 71/183 reads (39%) | catalogued as rs201790117; called by muse, mutect2, varscan2
- VPS28 | c.549-59G>A | Intron (SNP) | VAF 40/228 reads (18%) | catalogued as rs782640000, COSV52871291; called by muse, mutect2, varscan2
- WNK2 | chr9:93318433 C>T | 3'Flank (SNP) | VAF 37/146 reads (25%) | catalogued as COSV52931019; called by muse, mutect2, varscan2
